Somatic mutation profile of tumor specimen TARGET-40-NAAWGC-01A (aliquot TARGET-40-NAAWGC-01A-01D) from TARGET case TARGET-40-NAAWGC, project TARGET-OS (Osteosarcoma). Sex at birth: male; Primary diagnosis: Osteosarcoma, NOS; Age at diagnosis: 14.0 years (5,110 days).
Specimen TARGET-40-NAAWGC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6176fe74-11ce-4785-9606-2dc0d197dc1e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAWGC-10A (Blood Derived Normal), aliquot TARGET-40-NAAWGC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b72e2026-e084-4189-ba73-74f83e944941

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM4C | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs774865352, COSV67188896; called by muse, mutect2, varscan2
- ADGRV1 | c.15704A>G p.N5235S | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- DNAI4 | c.2015A>G p.D672G | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRP1 | c.3613G>A p.V1205M | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CAMSAP1 | c.2250C>T p.H750= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as rs536776836; called by muse, mutect2, varscan2
- ICAM1 | c.1440G>A p.E480= | Silent (SNP) | VAF 161/303 reads (53%) | catalogued as rs769933648; called by muse, mutect2, varscan2
- SMARCA4 | c.3753G>A p.L1251= | Silent (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
